Somatic mutation profile of tumor specimen 0DX4FO from CCDI case PBCPML, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: female; Primary diagnosis: Papillary carcinoma, follicular variant; Tissue or organ of origin: Thyroid gland; Age at diagnosis: 18.1 years (6,593 days).
Specimen 0DX4FO: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 92a305a9-07be-4276-a85a-78a567363763.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DX4ER (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/41da856c-aeb4-4218-91c5-29eb4b69281c

The open-access MAF lists 28 somatic variants for this specimen: 21 protein-altering or splice-affecting, 4 silent, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 17, Silent 4, Intron 3, Nonsense Mutation 3, Splice Region 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ACLY | c.1048G>A p.V350M | Missense Mutation (SNP) | VAF 570/1299 reads (44%) | SIFT deleterious (0); PolyPhen possibly damaging (0.834); catalogued as COSV61252979; called by muse, mutect2, varscan2
- CEACAM4 | c.352G>A p.G118R | Missense Mutation (SNP) | VAF 266/649 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs201885392; called by muse, mutect2, varscan2
- DICER1 | c.5438A>T p.E1813V | Missense Mutation (SNP) | VAF 376/949 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV58615258, COSV58615306, COSV58615741; called by muse, mutect2, varscan2
- EGFLAM | c.2179C>T p.Q727* | Nonsense Mutation (SNP) | VAF 413/1191 reads (35%) | catalogued as COSV100380541; called by muse, mutect2, varscan2
- FBLN5 | c.628G>A p.E210K | Missense Mutation (SNP) | VAF 194/424 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV50908202; called by muse, mutect2, varscan2
- MLXIPL | c.880G>A p.D294N | Missense Mutation (SNP) | VAF 327/835 reads (39%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.992); catalogued as COSV100515282; called by muse, mutect2, varscan2
- POTEG | c.17G>A p.G6D | Missense Mutation (SNP) | VAF 28/310 reads (9%) | SIFT tolerated, low confidence (0.92); PolyPhen benign (0.003); catalogued as rs1158545399, COSV101611959, COSV73630703; called by muse, varscan2
- RPGR | c.1244G>A p.R415K | Missense Mutation (SNP) | VAF 288/748 reads (39%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.621); catalogued as CD032754; called by muse, mutect2
- SMR3A | c.62A>T p.E21V | Missense Mutation (SNP) | VAF 183/454 reads (40%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.998); catalogued as rs1320488382; called by muse, mutect2, varscan2
- ARHGAP36 | c.276C>A p.N92K | Missense Mutation (SNP) | VAF 627/1758 reads (36%) | SIFT tolerated (0.81); PolyPhen benign (0.051); called by muse, mutect2, varscan2
- CD1C | c.352G>T p.A118S | Missense Mutation (SNP) | VAF 160/1551 reads (10%) | SIFT tolerated (0.14); PolyPhen benign (0.127); called by muse, mutect2, varscan2
- CNPPD1 | c.494G>A p.G165D | Missense Mutation (SNP) | VAF 277/680 reads (41%) | SIFT tolerated (0.35); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- DAB2 | c.250C>T p.R84W | Missense Mutation (SNP) | VAF 373/1010 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- DICER1 | c.3506C>G p.S1169* | Nonsense Mutation (SNP) | VAF 416/1122 reads (37%) | called by muse, mutect2, varscan2
- DNAH6 | c.4353A>T p.T1451= | Splice Region (SNP) | VAF 284/695 reads (41%) | called by muse, mutect2, varscan2
- ENPP7 | c.373C>A p.P125T | Missense Mutation (SNP) | VAF 353/892 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- MAP4K2 | c.1120G>A p.E374K | Missense Mutation (SNP) | VAF 417/1053 reads (40%) | SIFT tolerated (0.14); PolyPhen benign (0); called by muse, mutect2, varscan2
- NPAS4 | c.2239T>C p.S747P | Missense Mutation (SNP) | VAF 34/352 reads (10%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.55); called by muse, mutect2
- TMEM129 | c.892G>A p.V298M | Missense Mutation (SNP) | VAF 166/553 reads (30%) | SIFT tolerated (0.21); PolyPhen possibly damaging (0.64); called by muse, varscan2
- UBQLNL | c.82T>G p.S28A | Missense Mutation (SNP) | VAF 449/1215 reads (37%) | SIFT tolerated (1); PolyPhen benign (0.039); called by muse, mutect2, varscan2
- ZNF267 | c.361G>T p.E121* | Nonsense Mutation (SNP) | VAF 356/932 reads (38%) | called by mutect2, varscan2
- ADIPOQ | c.607C>T p.L203= | Silent (SNP) | VAF 474/1077 reads (44%) | called by muse, mutect2, varscan2
- ANO2 | c.858C>A p.A286= (on ENST00000356134 / NM_001278597.3; = p.A290= on NM_001278596.3) | Silent (SNP) | VAF 396/995 reads (40%) | catalogued as COSV59042951; called by muse, mutect2, varscan2
- KANK4 | c.1363C>T p.L455= | Silent (SNP) | VAF 588/1433 reads (41%) | called by muse, mutect2, varscan2
- LACTBL1 | c.64C>T p.L22= (on ENST00000618559; = p.L51= on NM_001289974.2) | Silent (SNP) | VAF 296/649 reads (46%) | called by muse, mutect2, varscan2
- DPP9 | c.2244+269del | Intron (DEL) | VAF 164/418 reads (39%) | called by mutect2, varscan2
- NIPBL | c.6955-84C>G | Intron (SNP) | VAF 6/65 reads (9%) | called by mutect2, varscan2
- UBE2F | c.283-76G>T | Intron (SNP) | VAF 22/100 reads (22%) | called by muse, mutect2, varscan2
